Somatic mutation profile of tumor specimen TCGA-B2-4102-01A (aliquot TCGA-B2-4102-01A-02D-1386-10) from TCGA case TCGA-B2-4102, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 61.6 years (22,492 days).
Specimen TCGA-B2-4102-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd7069e7-f586-446f-a9e4-6a9c197ba740.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-4102-11A (Solid Tissue Normal), aliquot TCGA-B2-4102-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d95e42db-d31c-4cb6-8a30-93dfd1617531

The open-access MAF lists 59 somatic variants for this specimen: 42 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 37, Silent 17, Frame Shift Del 3, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AOX1 | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs56199635, CM126500, COSV65982934; called by muse, mutect2, varscan2
- ARHGAP21 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV57609138; called by muse, mutect2, varscan2
- CGN | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 95/338 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as rs1297656228, COSV54972093; called by muse, mutect2, varscan2
- CLASP2 | c.3734A>G p.Y1245C (on ENST00000359576; = p.Y1244C on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV56288850; called by muse, mutect2
- CSNK1G1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.492); catalogued as rs759763094, COSV57312231; called by muse, mutect2, varscan2
- DIDO1 | c.5423C>T p.P1808L | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56629404; called by muse, mutect2, varscan2
- DLEC1 | c.3602T>G p.L1201R | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as COSV57303414; called by muse, mutect2, varscan2
- EQTN | c.827T>C p.I276T | Missense Mutation (SNP) | VAF 136/579 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV66219190; called by muse, mutect2, varscan2
- FAM124A | c.1253T>C p.L418P (on ENST00000322475 / NM_001242312.2; = p.L454P on NM_145019.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV54478585; called by muse, mutect2
- FASTKD1 | c.2198G>T p.C733F | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV71624572; called by muse, mutect2, varscan2
- GALNT8 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV52899618; called by muse, mutect2, varscan2
- GC | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as COSV56738608; called by muse, varscan2
- GP1BA | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56700212; called by muse, mutect2, varscan2
- HEPH | c.2555C>T p.A852V (on ENST00000343002; = p.A585V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV57968380; called by muse, mutect2, varscan2
- KCNA3 | c.976A>G p.N326D | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.21); catalogued as COSV63902231; called by muse, mutect2, varscan2
- KCNH6 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV59005872; called by muse, mutect2, varscan2
- KIAA1210 | c.2708A>G p.N903S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV101274429; called by mutect2, varscan2
- KIDINS220 | c.5155C>G p.P1719A | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV56756807, COSV99875760; called by muse, mutect2, varscan2
- KNL1 | c.5116G>A p.D1706N (on ENST00000346991 / NM_170589.5; = p.D1680N on NM_144508.5) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV61157979; called by muse, mutect2, varscan2
- LAMC1 | c.3532C>G p.L1178V | Missense Mutation (SNP) | VAF 70/392 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51157133; called by muse, mutect2, varscan2
- MAPK15 | c.1375G>T p.A459S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV100568130; called by muse, mutect2, varscan2
- MUS81 | c.1542G>C p.K514N | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV57260977; called by muse, mutect2, varscan2
- NFE2L1 | c.1124T>G p.F375C | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV62583610; called by muse, mutect2, varscan2
- NKAIN1 | c.413G>A p.C138Y | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55275231; called by muse, mutect2, varscan2
- NR2C2AP | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV57394222; called by muse, varscan2
- OR4D5 | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 135/576 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.633); catalogued as COSV58308402; called by muse, mutect2, varscan2
- PCDHA4 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs533708736, COSV100793789; called by muse, mutect2, varscan2
- PCM1 | c.322A>G p.N108D | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61518048; called by muse, mutect2
- PDE6A | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs768596256, COSV54926143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITRM1 | c.848A>C p.E283A | Missense Mutation (SNP) | VAF 80/406 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56536000; called by muse, mutect2, varscan2
- PKN3 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs549258373, COSV52578405; called by muse, mutect2, varscan2
- PLXND1 | c.4310C>T p.A1437V | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs762492313, COSV60710005; called by muse, mutect2, varscan2
- PTPRB | c.414del p.V139Sfs*68 | Frame Shift Del (DEL) | VAF 35/179 reads (20%) | catalogued as rs771024221; called by mutect2, pindel, varscan2
- PXN | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs766497021, COSV57220486; called by muse, mutect2, varscan2
- SLC44A2 | c.162C>G p.A54= | Splice Region (SNP) | VAF 43/177 reads (24%) | catalogued as COSV59838038, COSV59838607; called by muse, mutect2, varscan2
- SRRM2 | c.5429T>C p.V1810A | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as rs776086450, COSV100071586; called by muse, mutect2, varscan2
- TBC1D24 | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.15); catalogued as COSV53547656; called by muse, mutect2
- TCP11L2 | c.61T>A p.S21T | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as COSV100135419, COSV54431494; called by muse, mutect2, varscan2
- CCDC51 | c.700_716del p.L234Gfs*15 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- EPB41L4B | c.2220del p.K741Rfs*18 | Frame Shift Del (DEL) | VAF 29/189 reads (15%) | called by pindel, varscan2
- GTF2IRD2B | c.1507_1509del p.T503del | In Frame Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- IGHV1OR21-1 | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2
- ANKRD29 | c.414C>T p.I138= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as rs1225001373, COSV52426998, COSV99409135; called by muse, mutect2, varscan2
- C22orf23 | c.561C>T p.I187= | Silent (SNP) | VAF 94/464 reads (20%) | catalogued as rs200118186, COSV50778359; called by muse, mutect2, varscan2
- DAAM1 | c.2481T>G p.G827= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as COSV62838268; called by muse, mutect2, varscan2
- DCDC2 | c.819C>G p.P273= | Silent (SNP) | VAF 68/284 reads (24%) | catalogued as COSV65833160; called by muse, mutect2, varscan2
- HEXIM1 | c.126G>A p.E42= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV60177321; called by muse, mutect2, varscan2
- KIAA1549L | c.3298C>A p.R1100= (on ENST00000321505; = p.R1397= on NM_012194.3) | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs757475102, COSV55775832, COSV55777990; called by muse, mutect2, varscan2
- KRT6B | c.363C>A p.G121= | Silent (SNP) | VAF 64/477 reads (13%) | catalogued as rs554558110, COSV52884760, COSV52885231; called by muse, mutect2, varscan2
- LMF2 | c.1998G>T p.L666= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV53318377; called by muse, mutect2, varscan2
- LMO7 | c.4953G>A p.L1651= (on ENST00000357063; = p.L1332= on NM_005358.5) | Silent (SNP) | VAF 94/353 reads (27%) | catalogued as COSV58542810; called by muse, mutect2, varscan2
- NFE2L1 | c.1125C>T p.F375= | Silent (SNP) | VAF 52/282 reads (18%) | catalogued as COSV62583614; called by muse, mutect2, varscan2
- NKAIN1 | c.414C>T p.C138= | Silent (SNP) | VAF 39/200 reads (20%) | catalogued as rs539555175, COSV55274028; called by muse, mutect2, varscan2
- ODF2 | c.492G>A p.E164= (on ENST00000434106 / NM_153433.2; = p.E140= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 92/378 reads (24%) | catalogued as COSV63548194; called by muse, mutect2, varscan2
- OR10J3 | c.240C>G p.P80= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as COSV59955158; called by muse, mutect2
- RSKR | c.132T>C p.G44= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as COSV56383068; called by muse, mutect2, varscan2
- SETMAR | c.45G>A p.A15= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV62781204; called by muse, mutect2, varscan2
- TRAJ44 | c.64G>A p.*22= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs947980820; called by muse, mutect2, varscan2
- ZNF462 | c.2637C>A p.P879= | Silent (SNP) | VAF 38/198 reads (19%) | catalogued as COSV52946540; called by muse, mutect2, varscan2
